Somatic mutation profile of tumor specimen TCGA-P5-A737-01A (aliquot TCGA-P5-A737-01A-11D-A32B-08) from TCGA case TCGA-P5-A737, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 47.6 years (17,390 days).
Specimen TCGA-P5-A737-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e9af8d7-8125-433e-bfaa-85543d82ed30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A737-10A (Blood Derived Normal), aliquot TCGA-P5-A737-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b67232d3-a937-4945-926e-8695c2fa981d

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/41 reads (61%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.2659A>G p.M887V | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1279763571, COSV101330041; called by muse, mutect2, varscan2
- AHDC1 | c.3311G>A p.G1104E | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as COSV99899297; called by muse, mutect2, varscan2
- CRACD | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746752030, COSV51716359; called by muse, mutect2
- DHRS9 | c.364A>C p.T122P | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs770528035, COSV100513482; called by muse, mutect2, varscan2
- FSIP2 | c.19329A>G p.I6443M | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.949); catalogued as COSV100555123; called by muse, mutect2, varscan2
- H1-6 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV100619541; called by muse, mutect2, varscan2
- MOV10L1 | c.3019G>C p.E1007Q | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV99433768; called by muse, mutect2, varscan2
- NLRC3 | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.537); catalogued as rs746033653, COSV100072806; called by muse, mutect2, varscan2
- PHIP | c.293A>C p.Q98P | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.295); catalogued as COSV99244097; called by muse, mutect2, varscan2
- PLXNA3 | c.4375G>A p.A1459T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100859982; called by muse, mutect2
- SZT2 | c.6550C>T p.R2184C (on ENST00000634258 / NM_001365999.1; = p.R2127C on NM_015284.4) | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65172487; called by muse, mutect2, varscan2
- TTC23 | c.1262C>G p.S421* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100018737; called by muse, mutect2, varscan2
- ZNF333 | c.1916C>G p.T639S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99469138; called by muse, mutect2
- WDR70 | c.1364del p.F455Sfs*13 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by mutect2, pindel, varscan2
- CBLIF | c.30C>T p.S10= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as COSV99950943; called by muse, mutect2, varscan2
- OCA2 | c.1689G>A p.P563= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs758505248, COSV100667862; called by mutect2, varscan2
- SLC38A2 | c.696T>C p.F232= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV99873906; called by muse, mutect2, varscan2
